Surgical pathology report (de-identified scan), TCGA case TCGA-24-1425, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1425-01A (Primary Tumor).

[page 1 of 3]
Patient Name:

Address:

Gender:

DOB:

Service:

Location:

MRN :

Hospital #:

Patient Type

Accession #:

Taken:

Received:

Accessioned:

Reported:

DIAGNOSIS:

OVARY, RIGHT, SALPINGO-OOPHORECTOMY

- HIGH GRADE SEROUS CARCINOMA, EXTENDING TO THE OVARIAN SURFACE

OVARY, LEFT, SALPINGO-OOPHORECTOMY

- HIGH GRADE SEROUS CARCINOMA, EXTENDING TO THE OVARIAN SURFACE

FALLOPIAN TUBE, RIGHT, SALPINGO-OOPHORECTOMY

- NO HISTOPATHOLOGIC ABNORMALITY

FALLOPIAN TUBE, LEFT, SALPINGO-OOPHORECTOMY

- NO HISTOPATHOLOGIC ABNORMALITY

UTERUS, CERVIX, TOTAL ABDOMINAL HYSTERECTOMY

- MILD CHRONIC INFLAMMATION

UTERUS, ENDOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY

- WEAKLY PROLIFERATIVE ENDOMETRIUM

UTERUS, MYOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY

- LEIOMYOMA (0.4 CM)

UTERUS, SEROSA, TOTAL ABDOMINAL HYSTERECTOMY

- HIGH GRADE SEROUS CARCINOMA AND FIBROUS ADHESIONS

OMENTUM, EXCISION

- HIGH GRADE SEROUS CARCINOMA (19.0 CM)

BLADDER, SEROSA, "BLADDER TUMOR," BIOPSY (INCLUDING FS1)

- HIGH GRADE SEROUS CARCINOMA INVOLVING FIBROADIPOSE TISSUE

[page 2 of 3]
I. SURGICAL PATHOLOGY REPORT

Intraoperative Consultation:

An intraoperative non-microscopic consultation was obtained and interpreted as: "Called to pick up 'bladder tumor,' consisting of an irregular fragment of tan-pink soft tissue measuring 2.5 x 2.0 x 0.8 cm. Serially sectioned and one section is frozen as 'FS1.' Rest for permanents," by [REDACTED]

FS1: Bladder tumor, "ovarian cancer vs melanoma," biopsy
- "Poorly differentiated adenocarcinoma, favor Mullerian," by [REDACTED]

Microscopic Description and Comment:

The high grade serous carcinoma has papillary serous, microcystic and unclassified adenocarcinoma patterns. (D: [REDACTED])

History:

The patient is a [REDACTED] [REDACTED] also has a history of a melanoma on her right arm in [REDACTED]. Operative procedure: Total abdominal hysterectomy, bilateral salpingo-oophorectomy, omentectomy, and radical tumor debulking.

Specimen(s) Received:

A: BLADDER TUMOR
B: UTERUS, TUBES AND OVARIES
C: OMENTUM

Gross Description:

The specimens are received in three formalin-filled containers, each labeled [REDACTED]. The first container is labeled "bladder tumor 'ovarian cancer vs melanoma', FS1." It contains a white cassette labeled "FS1," that holds a portion of yellow-tan tissue measuring 2.5 x 0.6 x 0.2 cm. Also in the container are multiple fragments of yellow-tan tissue measuring in aggregate, 2.5 x 0.8 x 0.2 cm. Labeled A1 (FS1); A2 (X). Jar 0.

The second container is labeled "uterus, tubes and ovaries." It contains a 180 gram, 7.3 cm superior to inferior, 4.5 cm cornu to cornu, and 3.6 cm anterior to posterior uterus with attached cervix and bilateral adnexa. The serosal surfaces are rough with adhesions and putative tumor, anteriorly and posteriorly. The 3.0 x 2.7 cm pink, glistening ectocervix is tan with focal pinpoint hemorrhages. The 2.7 cm endocervical canal is tan and unremarkable. The 2.5 x 1.6 cm endometrial cavity is tan and unremarkable. The endometrial thickness measures 0.1 cm. The myometrium is tan and unremarkable and has a thickness of 1.9 cm. The 6.5 x 4.0 x 2.5 cm left ovary has tan, papillary tumor nodules on its surface, ranging from 0.2 to 1.4 cm. Sectioned to show a heterogeneous tan and red, partially solid and partially cystic cut surface. The cystic areas measure up to 1.5 cm and are filled with serous fluid. The 6.5 x 1.7 cm left fallopian tube has a tan, smooth serosal surface and is sectioned to show a tan, edematous cut surface with a pinpoint lumen. The 5.0 x 3.3 x 2.9 cm right ovary has a nodular serosal surface and is sectioned to show a solid and cystic, heterogeneous, tan and red cut surface. The cysts measure up to 2.0 cm and are filled with hemorrhagic material. The 6.0 x 1.0 cm right fallopian tube has a smooth brown serosal surface with focal adhesions and a tan cut surface with a pinpoint lumen. Labeled B1 to B3 - contiguous anterior strip with B1 containing cervix, B2 containing lower uterine segment, and B3 containing endometrium; B4 to B6 - contiguous posterior strip with B4 containing cervix, B5 containing lower uterine segment and B6 containing endometrium; B7 to B11 - left ovary with B7 containing surface tumor and fallopian tube; B12 to B14 - right ovary with B12 containing possible surface tumor and fallopian tube; B15, B16 - serosal tumor/adhesions. Jar 3.

The third container is labeled "total omentectomy." It contains numerous fragments of tan-red fibroadipose tissue nearly completely replaced by tumor, measuring 19 x 16 x 4.0 cm in aggregate. Sectioned to show yellow, firm fibroadipose tissue, diffusely infiltrated by tan tumor. Labeled C1. Jar 3.

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

HISTOPATHOLOGIC TYPE

The histologic diagnosis is serous adenocarcinoma

TUMOR LOCATION

right and left ovary

HISTOLOGIC GRADE

The histologic grade is poorly differentiated (G3)

TUMOR INVASION

Tumor is identified on the ovarian surface(s)

TUMOR INVOLVEMENT

Tumor involvement of the pelvic peritoneum/soft tissue is present

Metastatic involvement of the omentum is present

TUMOR SIZE

The maximum dimension of tumor implants outside the true pelvis is greater than or equal to 2 cm

PRIMARY TUMOR (T)

Based on the above information, the primary tumor is classified as macroscopic peritoneal metastasis beyond pelvis more than 2 cm in greatest dimension or regional lymph node metastasis (T3c/IIIC)

REGIONAL LYMPH NODES (N)

The regional lymph nodes cannot be assessed (NX)

DISTANT METASTASIS (M)

The status of distant tumor site cannot be assessed (MX)

STAGE GROUPING

The Final AJCC/UICC/FIGO stage is T3c/NX/MX

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Source: NCI Genomic Data Commons file 9d93339a-1429-48f5-ad3f-dddb1e770d0c (TCGA-24-1425.06592570-BE8F-49D4-A42F-068AD60EFE34.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).